Somatic mutation profile of tumor specimen TCGA-DK-AA6X-01A (aliquot TCGA-DK-AA6X-01A-12D-A42E-08) from TCGA case TCGA-DK-AA6X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 63.5 years (23,208 days).
Specimen TCGA-DK-AA6X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0f799d6-c5a4-43f0-9001-df2c210cb7b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6X-10A (Blood Derived Normal), aliquot TCGA-DK-AA6X-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d02818-8581-401a-b42a-69bcc38dde51

The open-access MAF lists 115 somatic variants for this specimen: 89 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 24, Nonsense Mutation 9, Intron 1, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 29/120 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57246521; called by muse, mutect2, varscan2
- KDM6A | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | hotspot (GDC flag); catalogued as COSV65043901; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2
- ALKBH6 | c.242G>T p.R81L (on ENST00000252984 / NM_001297701.2; = p.R109L on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV53324121, COSV53325024; called by muse, mutect2
- ANKLE2 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61710122; called by muse, mutect2, varscan2
- ATF6B | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV64352076; called by muse, mutect2, varscan2
- ATR | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV63387875, COSV63392953; called by muse, mutect2, varscan2
- BTBD9 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV58422636; called by muse, mutect2, varscan2
- CACNA1D | c.1955C>T p.S652L (on ENST00000350061 / NM_001128840.3; = p.S672L on NM_000720.4) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55452771; called by muse, mutect2, varscan2
- CACNA1G | c.5992C>A p.L1998I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.468); catalogued as rs1196100116, COSV61721960, COSV61730956; called by muse, mutect2, varscan2
- CCDC6 | c.1227C>G p.I409M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV54057525; called by muse, mutect2, varscan2
- CDKN1B | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM112450, COSV57430755; called by muse, mutect2, varscan2
- CFTR | c.2665C>G p.L889V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs61738523, COSV50065195; called by muse, mutect2, varscan2
- CLMP | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV71649982; called by muse, mutect2, varscan2
- DCHS1 | c.6380G>A p.R2127H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs142577975; called by muse, varscan2
- DHRS4L2 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV58730091, COSV58730130; called by muse, mutect2, varscan2
- DHX57 | c.2522G>T p.G841V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV54886959; called by muse, mutect2, varscan2
- EIF5 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53685809; called by muse, mutect2, varscan2
- ENTPD5 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.934); catalogued as COSV58222695; called by muse, mutect2, varscan2
- EPHA3 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60702005, COSV60712232; called by muse, mutect2, varscan2
- ERLEC1 | c.689C>G p.T230R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51752341; called by muse, mutect2, varscan2
- F11R | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57038499; called by muse, mutect2
- FAM91A1 | c.782C>G p.S261* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100593773, COSV58236572; called by muse, mutect2, varscan2
- FCRL6 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58940914, COSV58941558; called by muse, mutect2, varscan2
- FOLH1 | c.2073C>G p.I691M | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs963654912, COSV57052818; called by muse, mutect2, varscan2
- FXR2 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.057); catalogued as COSV51517738, COSV51519290; called by muse, mutect2, varscan2
- GON4L | c.4448C>T p.S1483F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV55196447; called by muse, mutect2, varscan2
- GYS2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53923456, COSV53924924; called by muse, mutect2, varscan2
- H2BC3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV63551149; called by muse, mutect2, varscan2
- H3C11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV58899154; called by muse, mutect2, varscan2
- IPO7 | c.1336-1G>A p.X446_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV63352743; called by muse, mutect2, varscan2
- IPO7 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV63352746; called by muse, mutect2, varscan2
- ITGB8 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56010468; called by muse, mutect2, varscan2
- ITIH5 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as COSV53668734, COSV99905350; called by muse, mutect2, varscan2
- KALRN | c.3517G>C p.E1173Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53757060, COSV53769802; called by muse, mutect2, varscan2
- KCNA10 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV63904868; called by muse, mutect2, varscan2
- KCTD9 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99648808; called by muse, mutect2, varscan2
- KLHL24 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99665134; called by muse, mutect2
- LBR | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1344394948, COSV55289715; called by muse, mutect2, varscan2
- LEO1 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV55176292; called by muse, mutect2, varscan2
- MARS2 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV56571648; called by muse, mutect2, varscan2
- MOAP1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.222); catalogued as COSV52092420; called by muse, mutect2, varscan2
- MUC5B | c.14923C>T p.Q4975* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV101500698; called by muse, mutect2, varscan2
- MYH11 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55558090; called by muse, mutect2, varscan2
- NAP1L1 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1382604262, COSV53875134; called by muse, mutect2, varscan2
- NDE1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV61271904; called by muse, mutect2, varscan2
- NEK1 | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV71456585; called by muse, mutect2, varscan2
- NF1 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV62194144, COSV62219192; called by muse, mutect2, varscan2
- NT5C | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1357340977, COSV55461140; called by muse, mutect2
- OLIG3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV62988761; called by muse, mutect2, varscan2
- OR1M1 | c.529T>A p.Y177N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV70037058; called by muse, mutect2, varscan2
- PAAF1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60156041; called by muse, mutect2, varscan2
- PDCL | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV52343616; called by muse, mutect2, varscan2
- PHKB | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV54525269; called by muse, mutect2, varscan2
- POLM | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV54243020; called by muse, mutect2, varscan2
- PSG3 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV100549222; called by muse, mutect2
- PSG7 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs782078128, COSV68445489; called by muse, mutect2, varscan2
- RELA | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58014936, COSV58015150; called by muse, mutect2, varscan2
- RFX5 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV51839844, COSV51840184; called by muse, mutect2, varscan2
- RFX6 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV60586421; called by muse, mutect2, varscan2
- RIPOR2 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289808624, COSV52424062; called by muse, mutect2, varscan2
- RPS5 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV52190740; called by muse, mutect2, varscan2
- RYR2 | c.5024C>T p.A1675V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV63693225; called by muse, mutect2, varscan2
- SBF1 | c.1229T>G p.L410R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62368405; called by muse, mutect2, varscan2
- SCAF11 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as COSV101014611; called by muse, mutect2, varscan2
- SCAF11 | c.1981C>G p.Q661E | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.192); catalogued as rs1274997160, COSV65477362; called by muse, mutect2, varscan2
- SEMA6D | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs202186547, COSV60379417; called by muse, mutect2, varscan2
- SETX | c.4331C>T p.S1444F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV56388153; called by muse, mutect2, varscan2
- SF3B3 | c.2077T>G p.Y693D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56788800; called by muse, mutect2, varscan2
- SF3B3 | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100210167; called by muse, mutect2, varscan2
- SLC26A5 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100100035; called by muse, mutect2, varscan2
- SLC26A8 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs1317057097, COSV62886404; called by muse, mutect2, varscan2
- SLC2A9 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53323233, COSV53327247; called by muse, mutect2, varscan2
- SLC38A10 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.26); catalogued as rs755477591, COSV55843324; called by muse, mutect2, varscan2
- SLX4IP | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV57948020; called by muse, mutect2, varscan2
- SMG1 | c.3326C>G p.S1109* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV101246729; called by muse, mutect2, varscan2
- STAM2 | c.500A>T p.D167V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV55732272; called by muse, mutect2, varscan2
- TANGO6 | c.2454A>T p.Q818H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55767687; called by muse, mutect2, varscan2
- TARBP1 | c.3382G>T p.D1128Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV50189488; called by muse, mutect2, varscan2
- TAS1R3 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs1186056362, COSV100229812, COSV59566179; called by muse, mutect2
- TEKT2 | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52881269; called by muse, mutect2, varscan2
- TUT1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV53470626; called by muse, mutect2, varscan2
- UGT1A3 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV59391912; called by muse, mutect2, varscan2
- ZC3H7A | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV63270107; called by muse, mutect2, varscan2
- ZNF117 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1317079115, COSV51425998, COSV51430256; called by muse, mutect2
- ZNF583 | c.460C>G p.Q154E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52403124; called by muse, mutect2, varscan2
- MRC1 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2
- NAXD | c.659dup p.M222Yfs*5 | Frame Shift Ins (INS) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- ADD3 | c.618G>A p.L206= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV53323488, COSV53325627; called by muse, mutect2, varscan2
- CACNA1G | c.5247C>T p.L1749= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100662435; called by muse, mutect2
- CAD | c.2049G>C p.V683= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53028408; called by muse, mutect2, varscan2
- DHPS | c.144C>T p.A48= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52952445; called by muse, mutect2, varscan2
- EPG5 | c.1920G>A p.V640= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV56351636; called by muse, mutect2, varscan2
- FXR2 | c.309C>T p.V103= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV51519302; called by muse, mutect2, varscan2
- INPPL1 | c.1602C>T p.I534= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs570236237, COSV53356736; called by muse, mutect2, varscan2
- ISG15 | c.366C>T p.F122= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV101046065, COSV65106598; called by muse, mutect2, varscan2
- LARP1 | c.2373C>G p.L791= (on ENST00000518297 / NM_033551.3; = p.L714= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100304040; called by muse, mutect2
- NATD1 | c.132C>T p.L44= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1404596965, COSV67541114; called by muse, mutect2, varscan2
- NLRP10 | c.1893A>C p.I631= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV60780890; called by muse, mutect2, varscan2
- NUP43 | c.747A>G p.Q249= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV61190395; called by muse, mutect2, varscan2
- PCDHB3 | c.984C>T p.S328= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1210433689; called by muse, mutect2
- PGM3 | c.222A>G p.K74= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52284595; called by muse, mutect2, varscan2
- POM121C | c.2160C>T p.L720= (on ENST00000607367; = p.L478= on NM_001099415.3) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1320232849; called by muse, mutect2, varscan2
- PRICKLE2 | c.300G>A p.L100= (on ENST00000295902; = p.L44= on NM_198859.4) | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV55767872; called by muse, mutect2, varscan2
- QSOX1 | c.1110C>T p.F370= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV62579823, COSV62580817; called by muse, mutect2, varscan2
- RARRES2 | c.261C>T p.C87= | Silent (SNP) | VAF 98/446 reads (22%) | catalogued as COSV56231566; called by muse, mutect2, varscan2
- SCN4A | c.3909G>A p.K1303= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101438637; called by muse, mutect2
- SLC6A5 | c.2298C>T p.R766= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs534286800, COSV54224695, COSV54226610; called by muse, mutect2, varscan2
- TANC1 | c.1923A>G p.P641= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV55090652; called by muse, mutect2, varscan2
- TAS1R3 | c.1299G>A p.L433= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100229815; called by muse, mutect2
- TMCC2 | c.1443C>T p.S481= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1404234955, COSV58004474; called by muse, mutect2, varscan2
- TRAV36DV7 | c.321C>T p.I107= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs371690774; called by muse, varscan2
- AC024940.1 | n.2551G>C | RNA (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- MGAM | c.4618+3224G>A | Intron (SNP) | VAF 10/39 reads (26%) | catalogued as rs756584984, COSV72074562; called by muse, mutect2, varscan2
